Somatic mutation profile of cancer-model specimen HCM-CSHL-0881-C20-85B (3D Organoid, passage 2; aliquot HCM-CSHL-0881-C20-85B-01D-A85L-36), derived from the primary tumor of HCMI case HCM-CSHL-0881-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.6 years (23,582 days).
Specimen HCM-CSHL-0881-C20-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 681a6832-0596-4693-863e-9412e7bbd934.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0881-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0881-C20-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf31e2c4-12c7-47d6-b0f1-60a4276fdecd

The open-access MAF lists 134 somatic variants for this specimen: 95 protein-altering or splice-affecting, 32 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 32, Nonsense Mutation 6, Intron 5, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Translation Start Site 1, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 80/169 reads (47%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 129/391 reads (33%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 263/402 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 180/182 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AARS2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs1257232166; called by muse, mutect2
- ACTR6 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs747971263; called by muse, mutect2, varscan2
- ALLC | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 150/332 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1217639908; called by muse, mutect2, varscan2
- ANK3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 162/402 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1290278926, COSV55055997; called by muse, mutect2, varscan2
- APC | c.4199C>A p.S1400* | Nonsense Mutation (SNP) | VAF 171/304 reads (56%) | catalogued as CM995167, COSV57324455, COSV57326621, COSV57333132; called by muse, mutect2, varscan2
- ATP2A3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 154/156 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs763249532; called by muse, mutect2, varscan2
- BTBD11 | c.1783G>A p.D595N (on ENST00000280758 / NM_001018072.2; = p.D132N on NM_001017523.2) | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs142214499, COSV55019446; called by muse, mutect2, varscan2
- CATSPER1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 183/379 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs775808039; called by muse, mutect2, varscan2
- CEP44 | c.281dup p.Q95Afs*17 | Frame Shift Ins (INS) | VAF 79/164 reads (48%) | catalogued as rs1407057449; called by mutect2, pindel, varscan2
- CFAP47 | c.6011C>T p.T2004M | Missense Mutation (SNP) | VAF 147/236 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs187452817; called by muse, mutect2, varscan2
- CIT | c.1110C>T p.N370= | Splice Region (SNP) | VAF 55/159 reads (35%) | catalogued as rs1482489106; called by muse, mutect2, varscan2
- CLCN3 | c.2302A>G p.M768V | Missense Mutation (SNP) | VAF 151/258 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs770732784; ClinVar: uncertain significance; called by muse, mutect2
- COL4A5 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 477/741 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM983307; called by muse, mutect2, varscan2
- DLL4 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 238/491 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs959903939; called by muse, mutect2, varscan2
- FREM1 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 149/308 reads (48%) | catalogued as COSV66517595; called by muse, mutect2, varscan2
- GCNA | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 230/769 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs753996914, COSV65467330; called by muse, mutect2, varscan2
- GDAP1L1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 197/400 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1317759945; called by muse, mutect2, varscan2
- HAPLN4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 393/737 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV52270181, COSV52270566; called by muse, mutect2, varscan2
- KMT2B | c.6146C>T p.P2049L | Missense Mutation (SNP) | VAF 324/680 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs1214467241; called by muse, mutect2, varscan2
- LTA4H | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 30/167 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1352781721; called by muse, mutect2, varscan2
- MSTO1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 47/613 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs201897470; called by muse, mutect2
- NLRP5 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 252/504 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs548549332, COSV66765347; called by muse, varscan2
- NME4 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs1032134184; called by muse, mutect2
- OGDHL | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 211/457 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777515897, COSV65100677, COSV65104914; called by muse, mutect2, varscan2
- OR5D14 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 188/390 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59457985; called by muse, mutect2, varscan2
- OR6B3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs749990375, COSV60113622; called by muse, mutect2, varscan2
- P2RY2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 310/603 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs779320289; called by muse, mutect2, varscan2
- PCDHA2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 277/546 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1300605850, COSV65366143; called by muse, mutect2, varscan2
- PCDHB8 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 308/753 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50760973; called by muse, mutect2, varscan2
- PNPLA7 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 189/347 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs199774780, COSV52994502, COSV99479825; called by muse, mutect2, varscan2
- PSG3 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 123/296 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs752340246; called by muse, mutect2, varscan2
- PTK2B | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 238/437 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774798724, COSV57758578; called by muse, mutect2, varscan2
- RB1 | c.610del p.X204_splice | Splice Site (DEL) | VAF 165/231 reads (71%) | catalogued as CS030549, COSV57315273; called by mutect2, pindel, varscan2
- RBMX2 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 143/551 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV59729087; called by muse, mutect2, varscan2
- SDK1 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 219/423 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs560755388, COSV67360707; called by muse, mutect2, varscan2
- SLC38A3 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 149/309 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748954198; called by muse, mutect2, varscan2
- SLC9A8 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 240/458 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867374600; called by muse, varscan2
- SPAG17 | c.5143C>T p.R1715W | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs754534447, COSV100308022, COSV60468652, COSV60469688; called by muse, mutect2, varscan2
- SPOCD1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 256/520 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs372711065; called by muse, mutect2
- SYT15 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100970237, COSV65430712; called by mutect2, varscan2
- TCP11 | c.391C>T p.R131C (on ENST00000512012; = p.R69C on NM_018679.5) | Missense Mutation (SNP) | VAF 183/344 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs757908827; called by muse, mutect2
- TDRD12 | c.2824dup p.T942Nfs*22 (on ENST00000444215; = p.T947Nfs*22 on NM_001366102.1) | Frame Shift Ins (INS) | VAF 116/263 reads (44%) | catalogued as rs1400735732; called by mutect2, pindel, varscan2
- TGFBI | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 217/378 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311315252, COSV59349955; called by muse, varscan2
- TMEM61 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 220/476 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs200736187, COSV64873323; called by muse, mutect2
- TOR4A | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 298/628 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1467035277; called by muse, mutect2, varscan2
- TRPC5 | c.280G>C p.V94L | Missense Mutation (SNP) | VAF 295/872 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV53284228; called by muse, mutect2, varscan2
- USP42 | c.3178C>T p.R1060W | Missense Mutation (SNP) | VAF 293/604 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533131980; called by muse, mutect2, varscan2
- VWF | c.8332C>T p.R2778W | Missense Mutation (SNP) | VAF 217/353 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs368634026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFYVE26 | c.4510C>G p.Q1504E | Missense Mutation (SNP) | VAF 200/392 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV61333788; called by muse, mutect2, varscan2
- ZNF729 | c.3359C>T p.T1120M | Missense Mutation (SNP) | VAF 123/235 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs567431275; called by muse, mutect2, varscan2
- ADGRG6 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 175/366 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD2 | c.613G>C p.A205P | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ARHGEF9 | c.1364A>G p.Q455R | Missense Mutation (SNP) | VAF 14/464 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- ATE1 | c.1304G>A p.W435* | Nonsense Mutation (SNP) | VAF 168/329 reads (51%) | called by muse, mutect2
- AXIN2 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 325/618 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB1 | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 47/572 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- CCDC121 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 182/383 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- COL4A3 | c.3259C>T p.Q1087* | Nonsense Mutation (SNP) | VAF 17/494 reads (3%) | called by muse, mutect2
- DNAH11 | c.6917C>A p.A2306E | Missense Mutation (SNP) | VAF 175/418 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJA3 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EAF2 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- ETNK1 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FIGN | c.971C>A p.A324E | Missense Mutation (SNP) | VAF 222/411 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FLNA | c.7087G>A p.A2363T (on ENST00000369850 / NM_001110556.2; = p.A2355T on NM_001456.3) | Missense Mutation (SNP) | VAF 189/652 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FOXP1 | c.1019_1020del p.Q340Lfs*2 | Frame Shift Del (DEL) | VAF 110/278 reads (40%) | called by mutect2, pindel, varscan2
- GBP4 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- GPSM3 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 330/666 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by mutect2, varscan2
- H2AJ | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 175/262 reads (67%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.680A>C p.N227T | Missense Mutation (SNP) | VAF 234/252 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- IL24 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 33/469 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- KIF14 | c.2815C>A p.L939I | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KRTAP26-1 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 166/342 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PABPC5 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 423/617 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIEZO2 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 235/402 reads (58%) | SIFT tolerated (0.78); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIGK | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLCB3 | c.1966T>C p.S656P | Missense Mutation (SNP) | VAF 263/541 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEC | c.13555G>A p.E4519K (on ENST00000322810 / NM_201380.4; = p.E4409K on NM_000445.5) | Missense Mutation (SNP) | VAF 224/579 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC35F3 | c.226G>A p.V76M (on ENST00000366617 / NM_001300845.1; = p.V145M on NM_173508.4) | Missense Mutation (SNP) | VAF 336/780 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- SVEP1 | c.4546A>G p.T1516A | Missense Mutation (SNP) | VAF 284/537 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SYNJ1 | c.901T>A p.L301M | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2
- TBC1D3B | c.366G>C p.L122F | Missense Mutation (SNP) | VAF 115/795 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, varscan2
- THUMPD2 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- TNNT1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 166/320 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRPS1 | c.3677A>T p.D1226V (on ENST00000220888 / NM_001330599.2; = p.D1239V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/393 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC3 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- UNC5D | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 104/274 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2
- VPS13C | c.7011G>T p.E2337D (on ENST00000644861 / NM_020821.3; = p.E2294D on NM_017684.5) | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ZAN | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 327/681 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ZNF398 | c.1265G>A p.S422N (on ENST00000475153 / NM_170686.3; = p.S251N on NM_020781.4) | Missense Mutation (SNP) | VAF 269/533 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ZNF423 | c.923G>A p.C308Y (on ENST00000563137 / NM_001379286.1; = p.C300Y on NM_015069.4) | Missense Mutation (SNP) | VAF 245/248 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF506 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS14 | c.2583G>A p.K861= | Silent (SNP) | VAF 174/350 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.1050C>T p.H350= | Silent (SNP) | VAF 110/251 reads (44%) | catalogued as rs959420906, COSV66864960; called by muse, mutect2, varscan2
- ARL10 | c.114G>T p.R38= | Silent (SNP) | VAF 290/508 reads (57%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.2055G>A p.G685= | Silent (SNP) | VAF 45/592 reads (8%) | catalogued as rs1452374656; called by muse, mutect2
- DOCK2 | c.2355C>T p.Y785= | Silent (SNP) | VAF 73/185 reads (39%) | called by muse, mutect2, varscan2
- DSTYK | c.1848G>A p.E616= | Silent (SNP) | VAF 184/439 reads (42%) | called by muse, mutect2, varscan2
- FOXF2 | c.348G>A p.S116= | Silent (SNP) | VAF 297/566 reads (52%) | called by muse, mutect2, varscan2
- FRMD7 | c.1887G>A p.E629= | Silent (SNP) | VAF 198/701 reads (28%) | called by muse, mutect2, varscan2
- FRRS1L | c.159C>T p.D53= | Silent (SNP) | VAF 302/547 reads (55%) | catalogued as rs1311628457; called by muse, mutect2, varscan2
- IQSEC2 | c.3483G>A p.S1161= | Silent (SNP) | VAF 208/682 reads (30%) | called by muse, varscan2
- KCTD16 | c.819A>G p.E273= | Silent (SNP) | VAF 138/246 reads (56%) | catalogued as rs774598298, COSV72580756; called by muse, mutect2, varscan2
- KRT4 | c.765G>A p.K255= | Silent (SNP) | VAF 11/398 reads (3%) | called by muse, mutect2
- LRP1B | c.6279G>A p.G2093= | Silent (SNP) | VAF 162/306 reads (53%) | catalogued as rs779853688; called by muse, mutect2, varscan2
- LRP2 | c.8091T>C p.G2697= | Silent (SNP) | VAF 217/444 reads (49%) | catalogued as rs1347473904; called by muse, mutect2, varscan2
- MAGEL2 | c.1491G>A p.P497= | Silent (SNP) | VAF 341/672 reads (51%) | catalogued as rs1170154433; called by muse, varscan2
- MGAT5B | c.2169C>T p.D723= (on ENST00000569840 / NM_001199172.2; = p.D721= on NM_144677.3) | Silent (SNP) | VAF 192/375 reads (51%) | catalogued as rs148015153; called by muse, mutect2, varscan2
- MROH7 | c.2172G>A p.S724= | Silent (SNP) | VAF 215/530 reads (41%) | catalogued as rs185594387; called by muse, mutect2, varscan2
- MUC16 | c.20220T>C p.G6740= | Silent (SNP) | VAF 218/448 reads (49%) | called by muse, mutect2, varscan2
- OR5D16 | c.69G>T p.L23= | Silent (SNP) | VAF 218/426 reads (51%) | called by muse, mutect2, varscan2
- PHKA2 | c.51G>A p.L17= | Silent (SNP) | VAF 428/663 reads (65%) | called by muse, mutect2, varscan2
- PKP1 | c.1455C>T p.R485= | Silent (SNP) | VAF 202/475 reads (43%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4269G>A p.L1423= | Silent (SNP) | VAF 243/776 reads (31%) | called by muse, mutect2, varscan2
- PNMA6E | c.1887C>T p.N629= (on ENST00000445091 / NM_001367770.1; = p.N351= on NM_001351293.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 164/540 reads (30%) | catalogued as rs987970092; called by muse, mutect2, varscan2
- PTCHD3 | c.405C>T p.G135= | Silent (SNP) | VAF 294/536 reads (55%) | catalogued as rs767926978, COSV71257076; called by muse, mutect2, varscan2
- RORB | c.804A>C p.A268= (on ENST00000396204 / NM_001365023.1; = p.A257= on NM_006914.4) | Silent (SNP) | VAF 152/310 reads (49%) | called by muse, mutect2, varscan2
- SETD7 | c.12G>A p.P4= | Silent (SNP) | VAF 40/318 reads (13%) | called by muse, varscan2
- SLC44A4 | c.877C>T p.L293= | Silent (SNP) | VAF 335/660 reads (51%) | called by muse, mutect2, varscan2
- SLC45A3 | c.358C>T p.L120= | Silent (SNP) | VAF 147/671 reads (22%) | called by muse, mutect2, varscan2
- SLC46A2 | c.723C>T p.P241= | Silent (SNP) | VAF 258/546 reads (47%) | catalogued as rs577863419, COSV100953527, COSV65289956; called by muse, mutect2, varscan2
- SUPT6H | c.381C>T p.D127= | Silent (SNP) | VAF 184/398 reads (46%) | catalogued as rs772850101, COSV58925755; called by muse, mutect2, varscan2
- TET3 | c.4723C>T p.L1575= | Silent (SNP) | VAF 58/636 reads (9%) | called by muse, mutect2
- TUBB4B | c.1122C>T p.I374= | Silent (SNP) | VAF 71/818 reads (9%) | called by muse, mutect2
- ATP6V1D | chr14:67360161 C>A | 5'Flank (SNP) | VAF 150/365 reads (41%) | called by muse, mutect2
- CNOT3 | c.2037+58G>A | Intron (SNP) | VAF 63/594 reads (11%) | catalogued as rs774096047; called by muse, mutect2
- COP1 | c.-133T>C | 5'UTR (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- ICOSLG | c.898+370C>T | Intron (SNP) | VAF 128/572 reads (22%) | catalogued as rs1222022474; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+19979T>C | Intron (SNP) | VAF 158/364 reads (43%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+9640G>A | Intron (SNP) | VAF 330/636 reads (52%) | catalogued as COSV55922649; called by muse, mutect2, varscan2
- TTN | c.34354+361G>T | Intron (SNP) | VAF 57/221 reads (26%) | called by muse, mutect2, varscan2
